Surgical pathology report (de-identified scan), TCGA case TCGA-BW-A5NP, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site St. Joseph's Medical Center-(MD), specimen TCGA-BW-A5NP-01A (Primary Tumor).

[page 1 of 3]
PAGE 1

Specimen Inquiry
Jser: Lab Database:

AGE/SX:

STATUS:

REG DR:

Flags: *H *L = Critical H,L = Abnormal #=Delta ** = Alpha Abn * Mic Abn

SPEC #:

STATUS:

SUEM DR:

ENTERED:

ORDERED:

SPECIAL STAINS

SURGICAL PROCEDURES:

ADRENALECTOMY-U, CHOLECYSTECTOMY, RESECTION, REGIONAL LYMPH

CLINICAL HISTORY

PERTINENT CLINICAL HISTORY: HEP B (+).

GROSS DESCRIPTION

A. The specimen is submitted fresh as "right trisegment of liver" and consists of a lobe of liver weighing 1,840 grams and measuring 23 x 15 x 10 cm. The capsule is purple tan, focally hemorrhagic and exhibits a large lobulated area comprising approximately 50% of the surface. Sectioning reveals a large well circumscribed pink yellow tumor measuring 15 x 13.5 x 9 cm which abuts the capsule and approaches to within 1 cm of the inked (green) surgical margin. The uninvolved parenchyma is yellow tan to pink red in color. Representative sections are submitted, 8 (8) labeled "1" to "8":

Cassettes 1 and 2: Uninvolved parenchyma including surgical margin
Cassette 3: Tumor surgical margin
Cassettes 4-8: Representative tumor (capsule black)

Please note: A portion of tissue is submitted for TCGA research. Gross photographs have been taken.

B. The specimen is submitted fresh as "portal lymph node" and consists of a firm pink nodule measuring 1.5 x 1 x 1 cm. The specimen is sectioned and submitted in toto, 3 (1).

C. The specimen is submitted in formalin as "gallbladder" and consists of a gallbladder measuring 7 x 2.5 x 2.5 cm. The serosa is gray green and smooth. The lumen contains dark green thick bile. Calculi are not grossly identified. The wall measures 0.2 cm in thickness. The mucosa is dark green and granular. The cystic duct appears dilated but does not contain calculi and measures 0.7 cm in diameter. There is an adjacent 0.6 cm gray tan node. Representative sections are submitted, 3 (1).

ICD-O-3

Carcinoma, hepatocellular NOS

Site: Liver, hepatic NOS

GW 2/4/13

817613
C22.0

[page 2 of 3]
Specimen Inquiry

(Continued)

GROSS DESCRIPTION

(Continued)

D. The specimen is submitted fresh as "left adrenal gland" and consists of a moderately firm circumscribed mass weighing 68 grams and measuring 7 x 5 x 4 cm. There is a small amount of attached adipose tissue. Sectioning reveals a soft pink white lobulated circumscribed mass with a thin rim of apparent adrenal measuring up to 0.4 cm in thickness. Representative sections are submitted, 3 (2). The surgical margins are marked with black dye. Please note: Gross photographs have been taken.

FINAL DIAGNOSIS

- A. LIVER, RIGHT, TRISEGMENTECTOMY:
- HEPATOCELLULAR CARCINOMA (15 CM). SEE SYNOPTIC REPORT.
- B. LYMPH NODE, PORTAL, EXCISION:
- LYMPH NODE, NEGATIVE FOR TUMOR (0/1).
- C. GALLBLADDER, CHOLECYSTECTOMY:
- CHRONIC CHOLECYSTITIS WITH CHOLESTEROSIS.
- BENIGN CYSTIC LYMPH NODE.
- D. LEFT ADRENAL GLAND, ADRENALECTOMY:
- METASTATIC HEPATOCELLULAR CARCINOMA (7 CM).

SYNOPTIC REPORT

SYNOPTIC REPORT: LIVER (AND INTRAHEPATIC BILE DUCTS)
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: PARTIAL HEPATECTOMY (TRISEGMENTECTOMY)
TUMOR FOCALITY: UNIFOCA
TUMOR SIZE: 15 CM
HISTOLOGIC TYPE: HEPATOCELLULAR
HISTOLOGIC GRADE: POORLY DIFFERENTIATED (GRADE 3 OF 4, EDMONDSON AND STEINER)

TUMOR EXTENSION: TUMOR CONFINED TO LIVER.
INVASION OF ADJACENT ORGANS/STRUCTURES: ABSENT.

[page 3 of 3]
ACCT#:

(Continued)

SYNOPSIS REPORT

(Continued)

MACROSCOPIC VENOUS (LARGE VESSEL) INVASION (V): NOT IDENTIFIED.
MICROSCOPIC (SMALL VESSEL) INVASION (L): PRESENT.

MARGINS:

f,,, PARENCHYMAL: UNINVOLVED

f,,f,,, DISTANCE OF INVASIVE CARCINOMA TO CLOSEST MARGIN: 1 CM.

LYMPH NODES:

f,,, # INVOLVED/ # EXAMINED: 0/1

OTHER PERTINENT FINDINGS:

- UNINVOLVED LIVER SHOWS CHRONIC HEPATITIS (CLINICAL HISTORY OF HEPATITIS B) WITH FIBROUS PORTAL EXPANSION (ISHAK SCORE 3/6) AND MILD LOBULAR AND PORTAL INFLAMMATION WITHOUT INTERFACE ACTIVITY.
- MILD MACROVESICULAR STEATOSIS INVOLVING 5-10% OF LIVER PARENCHYMA.
- A TRICHROME STAIN HIGHLIGHTS FIBROUS PORTAL EXPANSION OF MOST PORTAL AREAS WITH OCCASIONAL NEAR PORTAL-PORTAL BRIDGING.

pTNM STAGE: pT2 pN0 pM1 (STAGE IVB)

Signed (Electronically) < SIGNATURE ON FILE >

PATHOLOGIST

Source: NCI Genomic Data Commons file c083d322-48a6-4583-a316-05aee5f8c99e (TCGA-BW-A5NP.D13029B5-B160-48FC-A556-9FBF8CAF4EDB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).